Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5855, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5855-01A (Primary Tumor).

[page 1 of 5]
TCGA--DU--5855

Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] [REDACTED] Right frontal brain tumor.

OPERATIVE DIAGNOSES

Operation/Specimen: A: Right frontal brain, excision biopsy
B: Right frontal brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. B. Brain, right frontal tumor, excision biopsy: Anaplastic oligoastrocytoma (WHO Grade III) (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis, with the exception of the tumor grade. The sections show a moderately cellular infiltrative neoplasm. Mucin-filled microcystic spaces are seen focally. The tumor cells mostly show oval to round nuclei, however some irregular and angulated forms are present. Numerous mini-gemistocytes and some astrocytic gemistocytes are present. Mild to moderate nuclear pleomorphism is seen, with a mitotic count of up to 2 to 3 per ten HPFs in areas of dense cellularity. Frequent apoptotic bodies are noted. No definite microvascular proliferation or areas of necrosis are seen. p53 shows moderate positivity in 50% of the tumor cells, whereas EMA is mostly negative. The Ki-67 labeling index is focally increased to approximately 15%.

Positive and negative controls show appropriate immunoreactivity.

MGMT promoter methylation is detected, and complete LOH for 1p/19q is not detected (see procedure addenda below).

[page 2 of 5]
The tumor shows mixed oligodendroglial/astrocytic cytology, but appears primarily oligodendroglial.

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block H stained slide was examined by a pathologist for subsequent tumor dissection. Sufficient tumor cells were present in the tissue block and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by [REDACTED]. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

[page 3 of 5]
determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S552, D19S219, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block. DNA extracted from a corresponding blood specimen was used as normal reference control.

A stained slide was examined for subsequent tumor dissection. Sufficient tumor cells were present in the tissue block and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 [REDACTED] backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as

[page 4 of 5]
required by [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Right frontal brain, excision biopsy: Glioma, consistent with low histological grade. 1 block + touch prep and crush prep cytology.

[REDACTED]

GROSS DESCRIPTION

[REDACTED] Right frontal brain, excision biopsy: CONTAINER LABEL: right frontal brain tumor
FIXATIVE: formalin
GENERAL: Received is a tan-pink mass, measuring 2.4 x 2.3 x 0.7 cm.
SECTIONS: 1-frozen section remnant, 2-3-remaining tissue, [REDACTED]

B. Right frontal brain, excision biopsy: CONTAINER LABEL: right frontal brain tumor
FIXATIVE: formalin
GENERAL: Received are multiple tan-white to gray fragments, aggregating to 4.1 x 2.5 x 1.8 cm.
SECTIONS: 3, [REDACTED]

[REDACTED]

[page 5 of 5]
MICROSCOPIC DESCRIPTION

ICD-9(s):

225.0 225.0

Histo Data

Part A: Right frontal brain, excision biopsy

Stain/cnt

Block

Ordered

Comment

FS H/E x 1

1

Please have immuno

run

MAP2.

*** End of Report ***

Source: NCI Genomic Data Commons file 20dbe2be-d89b-425c-a56a-d9815e25c9e5 (TCGA-DU-5855.BA07CD68-B0AC-4E98-BC4B-ABE3B9C9D4F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).